Somatic mutation profile of tumor specimen MBCProject_0128_T2_WES (aliquot MBCProject_0128_T2_WES_1) from CMI case MBCProject_0128, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.1 years (13,553 days).
Specimen MBCProject_0128_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a051d938-d1ec-4236-946e-bc0afe4fcd5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0128_SALIVA (Saliva), aliquot MBCProject_0128_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d773b4b-7073-4242-a05b-ac505e66da63

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Intron 3, RNA 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 70/421 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2402G>A p.S801N | Missense Mutation (SNP) | VAF 41/410 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs766122347; called by muse, mutect2
- BCAP31 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs782018233, COSV100798979; called by muse, mutect2
- DNAI1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749119217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs777315807, COSV61315666; called by muse, mutect2, varscan2
- FLG | c.11095C>T p.R3699W | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as rs748562991; called by muse, mutect2, varscan2
- MECOM | c.1811G>A p.R604Q (on ENST00000468789 / NM_001105078.4; = p.R792Q on NM_004991.4) | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs753395114, COSV52961431; called by muse, mutect2
- MET | c.4091C>T p.P1364L | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752791731, COSV59270568; ClinVar: uncertain significance; called by muse, mutect2
- NRIP1 | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs775003588; called by muse, mutect2, varscan2
- OR10X1 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV100936695; called by muse, varscan2
- PIAS3 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 263/823 reads (32%) | catalogued as rs868988923, COSV65171507; called by muse, mutect2, varscan2
- ALG9 | c.1777A>C p.N593H (on ENST00000614444 / NM_001352418.1; = p.N600H on NM_024740.2) | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); called by muse, mutect2
- ATF2 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ATF7IP | c.2984C>G p.S995C | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CCDC51 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.647); called by muse, mutect2
- DOCK11 | c.1787A>T p.D596V | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); called by muse, mutect2
- MSL2 | c.306C>G p.C102W | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCDH18 | c.2494T>C p.S832P | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2
- PLCB3 | c.2831G>T p.S944I | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- RUFY1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- SLC4A2 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- SP7 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.379); called by muse, mutect2
- TRANK1 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.571); called by muse, mutect2
- TRIM21 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2
- TRPM2 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2
- WDR62 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 54/480 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN16 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, varscan2
- AP2B1 | c.1422C>T p.H474= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs925357404; called by mutect2, varscan2
- CACNA1H | c.3732C>T p.D1244= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs755463348, COSV61989311; called by mutect2, varscan2
- CBLIF | c.418T>C p.L140= | Silent (SNP) | VAF 42/267 reads (16%) | catalogued as rs141917734, COSV57240078; called by muse, mutect2, varscan2
- GLIS2 | c.1479C>T p.G493= | Silent (SNP) | VAF 41/284 reads (14%) | catalogued as rs373227853; called by muse, mutect2, varscan2
- GPR50 | c.783T>C p.A261= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs752087419; called by mutect2, varscan2
- VAC14 | c.1008C>T p.D336= | Silent (SNP) | VAF 27/186 reads (15%) | catalogued as rs747778595; called by muse, mutect2, varscan2
- ZAN | c.1692A>G p.T564= | Silent (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- C1orf159 | c.579+45_579+46del | Intron (DEL) | VAF 14/87 reads (16%) | called by pindel, varscan2
- OR52B1P | n.27C>G | RNA (SNP) | VAF 12/88 reads (14%) | called by muse, varscan2
- RGS6 | c.1368+5280G>A | Intron (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- STAG3L2 | n.1023G>T | RNA (SNP) | VAF 18/232 reads (8%) | catalogued as rs1554426472; called by muse, mutect2
- TTN | c.34264+2764C>G | Intron (SNP) | VAF 6/78 reads (8%) | catalogued as COSV59955084; called by muse, mutect2
